Somatic mutation profile of tumor specimen TCGA-22-5481-01A (aliquot TCGA-22-5481-01A-31D-1945-08) from TCGA case TCGA-22-5481, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 72.3 years (26,419 days).
Specimen TCGA-22-5481-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f3985d4-0a50-4eaa-b08d-e6f0839805b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-22-5481-11A (Solid Tissue Normal), aliquot TCGA-22-5481-11A-01D-1945-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/94106153-f349-45ae-88d0-5661812d384c

The open-access MAF lists 328 somatic variants for this specimen: 249 protein-altering or splice-affecting, 65 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 210, Silent 65, Nonsense Mutation 16, Frame Shift Del 14, Intron 5, RNA 5, Splice Site 4, Frame Shift Ins 2, In Frame Del 2, 5'Flank 2, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 37/48 reads (77%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs587780073, CM035576, COSV52661201, COSV52686167, COSV53142556; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.4768G>A p.V1590I | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101330088; called by muse, mutect2, varscan2
- ACOX2 | c.484C>A p.L162I | Missense Mutation (SNP) | VAF 40/56 reads (71%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.669); catalogued as rs143801474, COSV100250196; called by muse, mutect2, varscan2
- ACTRT1 | c.855G>C p.K285N | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.137); catalogued as COSV100947610; called by muse, mutect2, varscan2
- ADAM18 | c.1213G>T p.D405Y | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55852466; called by muse, mutect2, varscan2
- ADAM19 | c.2636C>G p.A879G | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99977518; called by muse, mutect2, varscan2
- ADAMTS16 | c.2324G>T p.R775L | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.722); catalogued as COSV56983275, COSV99941580; called by muse, mutect2, varscan2
- AGBL2 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as COSV54091602; called by muse, mutect2, varscan2
- AHRR | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57091197; called by muse, mutect2, varscan2
- AMY1B | c.994G>A p.D332N | Missense Mutation (SNP) | VAF 45/537 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.243); catalogued as COSV100375566; called by muse, mutect2
- ANGPT2 | c.881C>G p.T294R | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV100290973; called by muse, mutect2
- ANLN | c.2795G>C p.S932T | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV99732419; called by muse, mutect2, varscan2
- APLNR | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200854787, COSV57242011; called by muse, mutect2, varscan2
- AQR | c.3260G>T p.R1087L | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as COSV50032266, COSV99334099; called by muse, mutect2, varscan2
- ARFGEF2 | c.3830T>A p.F1277Y | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); catalogued as COSV100904310; called by muse, mutect2, varscan2
- ARFGEF3 | c.5199A>T p.L1733F | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99293807; called by muse, mutect2, varscan2
- ARHGEF25 | c.1673C>T p.P558L | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.015); catalogued as rs981198557, COSV99678045; called by muse, mutect2, varscan2
- ARL16 | c.47G>C p.R16P | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.013); catalogued as COSV100230556; called by muse, mutect2, varscan2
- ARPC2 | c.776A>T p.K259M | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99826732; called by muse, mutect2, varscan2
- ASMTL | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs752429560, COSV67243706; called by muse, mutect2, varscan2
- ATP5F1A | c.676A>G p.I226V | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.442); catalogued as rs367927966; called by muse, mutect2, varscan2
- BABAM2 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV100568116; called by muse, mutect2, varscan2
- BAZ1A | c.4345G>A p.D1449N | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV62411648; called by muse, mutect2, varscan2
- BCL2A1 | c.57C>A p.C19* | Nonsense Mutation (SNP) | VAF 31/44 reads (70%) | catalogued as COSV99144340; called by muse, mutect2, varscan2
- BMP4 | c.912G>T p.K304N | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV99817000; called by muse, mutect2, varscan2
- BTN2A2 | c.1162G>T p.V388L | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV100760442; called by muse, mutect2, varscan2
- C1orf105 | c.470C>G p.T157R | Missense Mutation (SNP) | VAF 47/260 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV100877964; called by muse, mutect2, varscan2
- C1orf141 | c.31G>A p.V11I | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs757949844, COSV100924350; called by muse, mutect2, varscan2
- C4orf17 | c.110G>A p.R37K | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100430950; called by muse, mutect2, varscan2
- CAMTA1 | c.1858G>A p.D620N | Missense Mutation (SNP) | VAF 80/226 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.494); catalogued as COSV100350559; called by muse, mutect2, varscan2
- CCDC102B | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 25/59 reads (42%) | catalogued as COSV100103796, COSV60156942; called by muse, mutect2, varscan2
- CCDC170 | c.1377C>A p.D459E | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.029); catalogued as COSV53347391; called by muse, mutect2, varscan2
- CCL17 | c.188T>G p.V63G | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99537188; called by muse, mutect2, varscan2
- CDR1 | c.135G>T p.L45F | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV100983423, COSV65163978; called by muse, mutect2, varscan2
- CEACAM3 | c.295G>C p.E99Q | Missense Mutation (SNP) | VAF 47/310 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99705000; called by muse, mutect2, varscan2
- CHRM3 | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753237593, COSV55088244; called by muse, mutect2, varscan2
- CIP2A | c.2582A>G p.E861G | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs147038755, COSV99842960; called by muse, mutect2, varscan2
- CLEC14A | c.832G>C p.E278Q | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as COSV60563223, COSV60563655; called by muse, mutect2, varscan2
- CNTNAP2 | c.2335G>C p.G779R | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.275); catalogued as COSV100667206; called by muse, mutect2, varscan2
- CPS1 | c.1441A>T p.T481S | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV99243228; called by muse, mutect2, varscan2
- CRB1 | c.1561G>T p.A521S | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as rs1427834440, COSV100957927; called by muse, mutect2, varscan2
- CSMD3 | c.7864G>T p.A2622S (on ENST00000297405 / NM_001363185.1; = p.A2518S on NM_052900.3) | Missense Mutation (SNP) | VAF 44/64 reads (69%) | SIFT tolerated (0.74); PolyPhen benign (0.019); catalogued as COSV99836906; called by muse, mutect2, varscan2
- CSMD3 | c.1502A>C p.D501A (on ENST00000297405 / NM_001363185.1; = p.D397A on NM_052900.3) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99836910; called by muse, varscan2
- CTNND2 | c.2101G>A p.D701N | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.519); catalogued as COSV58879615; called by muse, mutect2, varscan2
- CXCL11 | c.68C>G p.P23R | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.694); catalogued as COSV100134919; called by muse, mutect2, varscan2
- CYP1B1 | c.1019A>C p.Q340P | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV99572727; called by muse, mutect2, varscan2
- DAPP1 | c.631A>G p.T211A | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV99596925; called by muse, mutect2
- DDR2 | c.1504G>A p.G502S | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1262598602, COSV100906618; called by muse, mutect2, varscan2
- DDX4 | c.204A>G p.R68= | Splice Region (SNP) | VAF 18/66 reads (27%) | catalogued as rs1046751047, COSV100737581; called by muse, mutect2, varscan2
- DEFB132 | c.256G>C p.D86H | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as COSV101212612, COSV66677154; called by muse, mutect2
- DHRS7C | c.153G>T p.K51N | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.451); catalogued as COSV100364758; called by muse, mutect2, varscan2
- DISP3 | c.3805dup p.H1269Pfs*115 | Frame Shift Ins (INS) | VAF 24/74 reads (32%) | catalogued as rs756156984; called by mutect2, varscan2
- DLK2 | c.94C>T p.H32Y | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as COSV99767404; called by muse, mutect2, varscan2
- DMBX1 | c.650G>T p.G217V | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.071); catalogued as COSV100760800; called by muse, mutect2, varscan2
- DNAJC10 | c.876G>A p.M292I | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99899364; called by muse, mutect2, varscan2
- DOCK10 | c.4327A>G p.I1443V | Missense Mutation (SNP) | VAF 46/79 reads (58%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.683); catalogued as COSV99289933; called by muse, mutect2, varscan2
- DPP10 | c.213G>C p.L71F | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as COSV100067295; called by muse, mutect2, varscan2
- DPP10 | c.214G>T p.E72* | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | catalogued as COSV100067299, COSV59667988; called by muse, mutect2, varscan2
- DRAM1 | c.149C>A p.P50H | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99315650; called by muse, mutect2, varscan2
- DUSP16 | c.962A>C p.E321A | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV99963196; called by muse, mutect2, varscan2
- EDRF1 | c.1456C>A p.L486I (on ENST00000356792 / NM_001202438.2; = p.L452I on NM_015608.2) | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV100523567; called by muse, mutect2, varscan2
- ELAPOR1 | c.2671G>T p.G891C | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100884444; called by muse, mutect2, varscan2
- ENAM | c.689A>G p.E230G | Missense Mutation (SNP) | VAF 25/188 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV101253147; called by muse, mutect2, varscan2
- ENOX2 | c.1669A>G p.I557V (on ENST00000338144 / NM_001382520.1; = p.I528V on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as COSV100584250; called by muse, mutect2, varscan2
- EPHA7 | c.375G>T p.L125F | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs767086353, COSV100992410; called by muse, mutect2, varscan2
- EPS8 | c.254A>T p.D85V | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs1333928176, COSV99843280; called by muse, mutect2
- EYA4 | c.504G>T p.Q168H | Missense Mutation (SNP) | VAF 56/87 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100765971; called by muse, mutect2, varscan2
- FAM13A | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.759); catalogued as rs116703634, COSV52008874; called by muse, mutect2, varscan2
- FAM81A | c.128C>G p.T43S | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV99893291; called by muse, mutect2, varscan2
- FAT4 | c.8479G>T p.G2827W | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100628944; called by muse, mutect2, varscan2
- FERD3L | c.288G>T p.R96S | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs1010137628, COSV51762920, COSV99284975; called by muse, mutect2, varscan2
- FFAR3 | c.564G>T p.M188I | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100588226; called by muse, mutect2, varscan2
- FGFRL1 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as rs985127013, COSV99294691; called by muse, mutect2, varscan2
- FLNA | c.7076G>T p.G2359V (on ENST00000369850 / NM_001110556.2; = p.G2351V on NM_001456.3) | Missense Mutation (SNP) | VAF 79/178 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV100774813; called by muse, mutect2, varscan2
- FLNA | c.4367C>T p.P1456L | Missense Mutation (SNP) | VAF 177/374 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV100774814; called by muse, mutect2, varscan2
- FMO5 | c.1549G>C p.G517R | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV99567151; called by muse, mutect2, varscan2
- FOCAD | c.2195G>T p.R732I | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100620497, COSV58094530; called by muse, mutect2, varscan2
- GAR1 | c.110G>T p.G37V | Missense Mutation (SNP) | VAF 50/87 reads (57%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.708); catalogued as COSV99901925; called by muse, mutect2, varscan2
- GBA | c.765C>G p.F255L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100516365, COSV59169688; called by muse, mutect2, varscan2
- GDF15 | c.790C>G p.L264V | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.653); catalogued as COSV99416184; called by muse, mutect2, varscan2
- GLI3 | c.287A>G p.H96R | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.111); catalogued as COSV101229908; called by muse, mutect2, varscan2
- GRID1 | c.2918G>T p.G973V | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100024504, COSV100025892; called by muse, mutect2, varscan2
- GTF2F2 | c.269G>A p.G90E | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.926); catalogued as COSV100477058; called by muse, mutect2, varscan2
- GYPC | c.134C>A p.P45Q | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as CD910525, COSV99391829; called by muse, mutect2, varscan2
- HAUS5 | c.950T>G p.V317G | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.087); catalogued as COSV99178766; called by muse, mutect2
- HMGCS1 | c.1100G>T p.G367V | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100285016; called by muse, mutect2, varscan2
- HSPG2 | c.4849C>G p.L1617V | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.987); catalogued as COSV101020763; called by muse, mutect2, varscan2
- IFNL2 | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.047); catalogued as COSV100122093; called by muse, mutect2, varscan2
- IFRD2 | c.1449C>A p.Y483* | Nonsense Mutation (SNP) | VAF 14/21 reads (67%) | catalogued as COSV100269574; called by muse, mutect2, varscan2
- INTS3 | c.484G>T p.G162C | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV100016153; called by muse, mutect2, varscan2
- IPO11 | c.1979A>G p.H660R | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV100321013, COSV57581576; called by muse, mutect2, varscan2
- IPO9 | c.2951A>T p.Y984F | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100843460, COSV64234149; called by muse, mutect2, varscan2
- IRF2BP1 | c.1456G>C p.V486L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1568637877, COSV100138911; called by muse, mutect2
- ITPRID1 | c.1969G>T p.A657S | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV100086643; called by muse, mutect2, varscan2
- KCNIP1 | c.417G>T p.R139S (on ENST00000411494 / NM_001034837.3; = p.R128S on NM_014592.4) | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.038); catalogued as COSV100199551; called by muse, mutect2, varscan2
- KCNQ2 | c.758C>A p.A253E | Missense Mutation (SNP) | VAF 85/172 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV100610298; called by muse, mutect2, varscan2
- KLF17 | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as rs761749908, COSV100954972; called by muse, mutect2, varscan2
- KMT2C | c.7312C>T p.P2438S | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100072825; called by muse, mutect2, varscan2
- LAMC1 | c.4124G>T p.R1375M | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as rs747294068, COSV99279751; called by muse, mutect2, varscan2
- LDB2 | c.983A>C p.Y328S | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.528); catalogued as COSV100453939, COSV58780024; called by muse, mutect2, varscan2
- LGR4 | c.2525A>T p.Y842F | Missense Mutation (SNP) | VAF 49/75 reads (65%) | SIFT tolerated (0.62); PolyPhen benign (0.388); catalogued as COSV100156604; called by muse, mutect2, varscan2
- LLGL2 | c.1255-1G>A p.X419_splice | Splice Site (SNP) | VAF 19/37 reads (51%) | catalogued as COSV99389934; called by muse, mutect2, varscan2
- LPAR2 | c.69G>T p.E23D | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV99179325; called by muse, mutect2, varscan2
- LRRC49 | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV99537660; called by muse, mutect2, varscan2
- LVRN | c.962C>T p.T321I | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.091); catalogued as COSV100773517; called by muse, mutect2, varscan2
- MAN2B2 | c.1031A>G p.H344R | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV99577572; called by muse, mutect2, varscan2
- MAN2C1 | c.2075G>A p.G692D | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.094); catalogued as COSV99145471; called by muse, mutect2, varscan2
- MARCO | c.901+1G>T p.X301_splice | Splice Site (SNP) | VAF 17/64 reads (27%) | catalogued as COSV100503573; called by muse, mutect2, varscan2
- MEFV | c.60C>G p.D20E | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.737); catalogued as rs747728640, COSV99561000; called by muse, mutect2, varscan2
- MIA3 | c.4264G>C p.E1422Q | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.338); catalogued as COSV100485073; called by muse, mutect2, varscan2
- MLLT10 | c.779C>A p.T260N | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.699); catalogued as COSV100308267; called by muse, mutect2, varscan2
- MORC1 | c.2671G>T p.D891Y | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV99226481; called by muse, mutect2
- MPP5 | c.1081G>A p.D361N | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99907145; called by muse, mutect2, varscan2
- MRPL53 | c.168G>C p.R56S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV99252162; called by muse, mutect2
- MS4A5 | c.489C>A p.F163L | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.051); catalogued as COSV100281024; called by muse, mutect2, varscan2
- MYH1 | c.1382G>T p.G461V | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99876167; called by mutect2, varscan2
- MYH7 | c.5543A>T p.K1848M | Missense Mutation (SNP) | VAF 71/95 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM133945, COSV100806218; called by muse, mutect2, varscan2
- MYH7B | c.1609A>C p.M537L | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV99482891; called by muse, mutect2, varscan2
- MYO7A | c.1946G>A p.R649Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1308203959, COSV101289165; called by muse, mutect2, varscan2
- NALCN | c.4047C>A p.Y1349* | Nonsense Mutation (SNP) | VAF 16/64 reads (25%) | catalogued as COSV51944848, COSV99215793; called by muse, mutect2, varscan2
- NANOS3 | c.77C>G p.P26R | Missense Mutation (SNP) | VAF 31/213 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.383); catalogued as COSV100188505; called by muse, mutect2, varscan2
- NFXL1 | c.1895C>T p.P632L | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as COSV100216850; called by muse, mutect2, varscan2
- NKG7 | c.181T>A p.F61I | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV99389897; called by muse, mutect2, varscan2
- NPHP1 | c.1679C>T p.S560L (on ENST00000393272 / NM_207181.4; = p.S561L on NM_000272.5) | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.231); catalogued as COSV100338215, COSV57208454; called by muse, mutect2, varscan2
- NRXN1 | c.3764G>T p.G1255V | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100640353; called by muse, mutect2, varscan2
- OPRPN | c.365C>A p.P122H | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.009); catalogued as COSV101271090; called by muse, mutect2, varscan2
- OR10G7 | c.776T>A p.L259Q | Missense Mutation (SNP) | VAF 31/47 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100389968, COSV57866023; called by muse, mutect2, varscan2
- OR10G7 | c.288C>A p.C96* | Nonsense Mutation (SNP) | VAF 26/150 reads (17%) | catalogued as COSV100389971, COSV57866856; called by muse, mutect2, varscan2
- OR13G1 | c.410T>A p.M137K | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV100687316; called by muse, mutect2, varscan2
- OR4N2 | c.502T>A p.F168I | Missense Mutation (SNP) | VAF 23/282 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100269682; called by muse, mutect2
- OR5AK2 | c.113C>G p.S38C | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100476053; called by muse, mutect2, varscan2
- OR5B17 | c.718G>T p.G240C | Missense Mutation (SNP) | VAF 30/43 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); catalogued as COSV100641910; called by muse, mutect2, varscan2
- OR5M1 | c.493C>T p.H165Y | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.808); catalogued as COSV101591578, COSV73202149; called by muse, mutect2, varscan2
- OR8H3 | c.200T>A p.L67Q | Missense Mutation (SNP) | VAF 56/222 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100539014; called by muse, mutect2, varscan2
- OSM | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.04); catalogued as COSV99304211, COSV99304309; called by muse, mutect2, varscan2
- PARP4 | c.407G>A p.G136D | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as COSV101131692; called by muse, mutect2, varscan2
- PCDH15 | c.3703A>T p.K1235* | Nonsense Mutation (SNP) | VAF 19/36 reads (53%) | catalogued as COSV100222143; called by muse, mutect2, varscan2
- PCDHA11 | c.2375C>A p.S792* | Nonsense Mutation (SNP) | VAF 3/9 reads (33%) | catalogued as COSV100251269; called by muse, mutect2
- PCDHA9 | c.2378C>G p.S793* | Nonsense Mutation (SNP) | VAF 30/62 reads (48%) | catalogued as COSV100969671; called by muse, mutect2, varscan2
- PCDHB16 | c.103G>A p.V35I | Missense Mutation (SNP) | VAF 61/124 reads (49%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs1554281999, COSV53358986; called by muse, mutect2, varscan2
- PDZD2 | c.1456A>T p.K486* | Nonsense Mutation (SNP) | VAF 16/79 reads (20%) | catalogued as COSV99225410; called by muse, mutect2, varscan2
- PIGG | c.1781A>G p.Y594C (on ENST00000453061 / NM_001127178.3; = p.Y586C on NM_017733.4) | Missense Mutation (SNP) | VAF 62/119 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99573994; called by muse, mutect2, varscan2
- PIKFYVE | c.1981A>G p.I661V | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.97); catalogued as COSV100010906; called by muse, mutect2, varscan2
- PKHD1L1 | c.1902G>T p.L634F | Missense Mutation (SNP) | VAF 53/78 reads (68%) | SIFT tolerated (0.14); PolyPhen benign (0.169); catalogued as COSV101006304; called by muse, mutect2, varscan2
- PLCE1 | c.1138G>T p.E380* | Nonsense Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as COSV99595294; called by muse, mutect2, varscan2
- PLCE1 | c.6053T>G p.V2018G | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV99595296; called by muse, mutect2, varscan2
- PLCXD3 | c.381G>T p.E127D | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.132); catalogued as COSV100125860; called by muse, mutect2, varscan2
- POLQ | c.3475A>G p.R1159G | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.057); catalogued as COSV99952384; called by muse, mutect2, varscan2
- PPFIA4 | c.2597C>T p.S866L (on ENST00000447715; = p.S867L on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769869925, COSV55313614; called by muse, mutect2, varscan2
- PRDM14 | c.1001C>A p.P334H | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99400249; called by muse, mutect2, varscan2
- PREX1 | c.717G>T p.E239D | Missense Mutation (SNP) | VAF 80/164 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100906458; called by muse, mutect2, varscan2
- PRKDC | c.2341G>C p.D781H | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100041057, COSV100041205; called by muse, mutect2, varscan2
- PRPF40A | c.2830A>G p.R944G | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.327); catalogued as COSV101344204; called by muse, mutect2, varscan2
- PRUNE2 | c.7584A>T p.K2528N | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as COSV100944721; called by muse, mutect2, varscan2
- PSMD8 | c.331A>G p.K111E | Missense Mutation (SNP) | VAF 24/32 reads (75%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as COSV99286615; called by muse, mutect2
- QDPR | c.478C>T p.L160F | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99845853; called by muse, mutect2, varscan2
- RAB39B | c.22C>T p.Q8* | Nonsense Mutation (SNP) | VAF 76/152 reads (50%) | catalogued as COSV101035000; called by muse, mutect2, varscan2
- RAE1 | c.439G>A p.G147R | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100982439; called by muse, mutect2, varscan2
- RANGAP1 | c.472G>A p.G158S | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.568); catalogued as COSV100663777; called by muse, mutect2, varscan2
- RASGEF1C | c.897G>A p.M299I | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as COSV63178018; called by muse, mutect2, varscan2
- RASSF5 | c.1165C>T p.Q389* | Nonsense Mutation (SNP) | VAF 50/101 reads (50%) | catalogued as COSV99662852; called by muse, mutect2, varscan2
- RB1 | c.455T>A p.L152* | Nonsense Mutation (SNP) | VAF 24/41 reads (59%) | catalogued as COSV99925193; called by muse, mutect2, varscan2
- RBM27 | c.712A>T p.S238C | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV99506256; called by muse, mutect2, varscan2
- RNF11 | c.162C>G p.S54R | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.255); catalogued as COSV99658008; called by muse, mutect2, varscan2
- RNF180 | c.1144A>G p.N382D | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV99684762; called by muse, mutect2, varscan2
- SALL3 | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1199538514, COSV101610013; called by muse, mutect2
- SCARA5 | c.871G>T p.D291Y | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100107934; called by muse, mutect2, varscan2
- SHC4 | c.1163T>G p.V388G | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV100194709; called by muse, mutect2, varscan2
- SHISAL1 | c.5C>T p.T2I | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.996); catalogued as rs368846763; called by muse, mutect2, varscan2
- SIPA1L1 | c.813C>G p.N271K | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.85); PolyPhen benign (0.025); catalogued as COSV100665649; called by muse, mutect2, varscan2
- SIPA1L3 | c.274G>T p.A92S | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.108); catalogued as COSV99729111; called by muse, mutect2
- SIPA1L3 | c.677G>C p.R226P | Missense Mutation (SNP) | VAF 12/175 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV55915238, COSV99729116; called by muse, mutect2
- SLC13A1 | c.1556C>G p.S519C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV99521053; called by muse, mutect2, varscan2
- SLC22A10 | c.1510T>C p.F504L | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT tolerated (0.44); PolyPhen benign (0.044); catalogued as rs1296108033, COSV100235814; called by muse, mutect2, varscan2
- SLC30A7 | c.22G>C p.D8H | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV100725541; called by muse, mutect2, varscan2
- SLC34A1 | c.1216A>T p.M406L | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.101); catalogued as COSV100183987; called by muse, mutect2, varscan2
- SLC6A5 | c.2319G>T p.M773I | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV100116957; called by muse, mutect2, varscan2
- SLC9C2 | c.1543G>C p.A515P | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.984); catalogued as COSV100876797; called by muse, mutect2, varscan2
- SLCO3A1 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs761312118, COSV100575536, COSV59234825; called by muse, mutect2, varscan2
- SNAP25 | c.302A>T p.Y101F | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.212); catalogued as COSV99654966; called by muse, mutect2, varscan2
- SP100 | c.2271C>A p.S757R | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.631); catalogued as COSV100414071, COSV60852815; called by muse, mutect2, varscan2
- SPAG17 | c.5491G>A p.E1831K | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV60464558; called by muse, mutect2, varscan2
- SPHKAP | c.2650C>A p.Q884K | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.494); catalogued as COSV100764208; called by muse, mutect2, varscan2
- SPRR2E | c.37C>A p.Q13K | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.007); catalogued as rs1465292083, COSV100907439; called by muse, mutect2, varscan2
- SUPT5H | c.2434A>T p.S812C | Missense Mutation (SNP) | VAF 55/326 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100782092; called by muse, mutect2, varscan2
- SUPT5H | c.2435G>A p.S812N | Missense Mutation (SNP) | VAF 55/318 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.854); catalogued as rs1482781355, COSV63239392; called by muse, mutect2, varscan2
- SUPT6H | c.2437del p.H813Ifs*24 | Frame Shift Del (DEL) | VAF 16/44 reads (36%) | catalogued as COSV58927189; called by mutect2, pindel, varscan2
- TAB3 | c.2045A>G p.Y682C | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.641); catalogued as COSV99916346; called by muse, mutect2, varscan2
- TACC1 | c.990C>A p.N330K | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0.039); catalogued as COSV99393575; called by muse, mutect2, varscan2
- TADA2B | c.616G>T p.V206L | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV53827725, COSV99380668; called by muse, mutect2, varscan2
- TAF1L | c.2149A>G p.T717A | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as COSV99644847; called by muse, mutect2, varscan2
- TAT | c.527C>A p.A176D | Missense Mutation (SNP) | VAF 38/48 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100587655; called by muse, mutect2, varscan2
- TBX18 | c.1309A>G p.T437A | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.147); catalogued as rs550371084, COSV100858530; called by muse, mutect2, varscan2
- TENT5D | c.407A>G p.K136R | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100382788; called by muse, mutect2, varscan2
- TEX101 | c.183G>C p.Q61H (on ENST00000598265 / NM_001130011.3; = p.Q79H on NM_031451.4) | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99494853; called by muse, mutect2, varscan2
- THOC2 | c.1249G>C p.A417P | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV99833528; called by muse, mutect2, varscan2
- TKTL1 | c.219G>T p.E73D | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV99474014; called by muse, mutect2, varscan2
- TLR1 | c.1560A>T p.K520N | Missense Mutation (SNP) | VAF 56/236 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV100458559; called by muse, mutect2, varscan2
- TNR | c.1540G>T p.D514Y | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54888590, COSV99687652; called by muse, mutect2, varscan2
- TPSB2 | c.728G>T p.S243I | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52355809; called by muse, mutect2
- TRIM59 | c.1173T>A p.Y391* | Nonsense Mutation (SNP) | VAF 15/36 reads (42%) | catalogued as COSV100557512; called by muse, mutect2, varscan2
- TTC5 | c.270G>T p.E90D | Missense Mutation (SNP) | VAF 35/233 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV99351858; called by muse, mutect2, varscan2
- TTC6 | c.1200+1G>T p.X400_splice (on ENST00000267368; = p.X1766_splice on NM_001310135.3) | Splice Site (SNP) | VAF 31/83 reads (37%) | catalogued as COSV99941944; called by muse, mutect2, varscan2
- TTN | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 19/77 reads (25%) | PolyPhen benign (0.027); catalogued as rs913566479, COSV100617472; called by muse, mutect2, varscan2
- USH2A | c.1444G>T p.A482S | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100236744; called by muse, mutect2, varscan2
- USP2 | c.1445G>C p.R482T | Missense Mutation (SNP) | VAF 70/219 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as COSV99489732; called by muse, mutect2, varscan2
- USP40 | c.880G>T p.V294F | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99296562; called by muse, mutect2
- VPS16 | c.1816C>A p.Q606K | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT tolerated (0.62); PolyPhen benign (0.095); catalogued as COSV100988507, COSV66794237; called by muse, mutect2, varscan2
- VWF | c.6904C>G p.P2302A | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.334); catalogued as COSV54633287, COSV99779340; called by muse, mutect2, varscan2
- YTHDF1 | c.998A>T p.N333I | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.395); catalogued as COSV100945576; called by muse, mutect2, varscan2
- YY1AP1 | c.2320C>A p.P774T (on ENST00000295566 / NM_139118.2; = p.P717T on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.06); catalogued as COSV99804221; called by muse, mutect2, varscan2
- ZDBF2 | c.5422A>T p.I1808L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs746101016, COSV100984995; called by muse, mutect2, varscan2
- ZFHX4 | c.6988C>A p.H2330N | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99263787; called by muse, mutect2, varscan2
- ZNF25 | c.1283G>T p.C428F | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100224659; called by muse, mutect2, varscan2
- ZNF335 | c.425G>T p.G142V | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100533113; called by muse, mutect2, varscan2
- ZNF395 | c.1079C>G p.T360S | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0.337); catalogued as rs757903586, COSV100733993; called by muse, mutect2, varscan2
- ZNF470 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1262553277, COSV100401271; called by muse, mutect2, varscan2
- ZNF479 | c.283C>T p.Q95* | Nonsense Mutation (SNP) | VAF 18/133 reads (14%) | catalogued as rs1342883510, COSV100482796; called by muse, mutect2, varscan2
- ZNF500 | c.206G>T p.S69I | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.939); catalogued as COSV99556371; called by muse, mutect2, varscan2
- ZNF532 | c.715G>A p.V239I | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV100266701; called by muse, mutect2, varscan2
- ZNF543 | c.614G>T p.G205V | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100386805; called by muse, mutect2, varscan2
- ZNF546 | c.2082A>G p.I694M | Missense Mutation (SNP) | VAF 7/172 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs759008966, COSV100713478; called by muse, mutect2
- ZNF585B | c.1738T>A p.C580S | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100459480; called by muse, mutect2, varscan2
- ZNF638 | c.3350C>T p.T1117I | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV100039064; called by muse, mutect2, varscan2
- ZNF772 | c.1466C>T p.P489L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV100582859; called by muse, mutect2, varscan2
- ZNF85 | c.1714G>A p.D572N | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs1455089486, COSV100059879, COSV100060131; called by muse, mutect2, varscan2
- ZNF91 | c.3323G>A p.C1108Y | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100322872; called by muse, mutect2, varscan2
- ZNF99 | c.1157A>T p.K386I | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.977); catalogued as COSV101233854; called by muse, mutect2, varscan2
- ANKRD20A4P | c.1721A>G p.Y574C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by mutect2, varscan2
- ASAH2 | c.1061C>A p.S354Y | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ATP6V1D | c.15_18del p.D5Efs*14 | Frame Shift Del (DEL) | VAF 11/35 reads (31%) | called by mutect2, pindel, varscan2
- CFAP65 | c.3438del p.C1147Vfs*13 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | called by mutect2, pindel, varscan2
- CRTC1 | c.1053_1059del p.Y352Sfs*51 | Frame Shift Del (DEL) | VAF 5/24 reads (21%) | called by mutect2, pindel
- CYP2B6 | c.600del p.L201Cfs*24 | Frame Shift Del (DEL) | VAF 25/167 reads (15%) | called by mutect2, pindel, varscan2
- EDRF1 | c.2383del p.A795Qfs*8 (on ENST00000356792 / NM_001202438.2; = p.A761Qfs*8 on NM_015608.2) | Frame Shift Del (DEL) | VAF 3/18 reads (17%) | called by mutect2, pindel, varscan2
- GAB4 | c.1212_1219del p.M405Rfs*7 | Frame Shift Del (DEL) | VAF 22/106 reads (21%) | called by mutect2, pindel, varscan2
- GPR142 | c.832del p.A278Pfs*6 | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | called by mutect2, pindel, varscan2
- LRGUK | c.2183_2186del p.P728Lfs*13 | Frame Shift Del (DEL) | VAF 17/54 reads (31%) | called by mutect2, pindel, varscan2
- MPPE1 | c.195dup p.R66Tfs*2 | Frame Shift Ins (INS) | VAF 8/25 reads (32%) | called by mutect2, pindel, varscan2
- OR5L1 | c.923A>G p.K308R | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2
- PSG8 | c.586_634del p.S196Qfs*12 | Frame Shift Del (DEL) | VAF 35/547 reads (6%) | called by mutect2, pindel
- RALGPS2 | c.1336_1341del p.S446_E447del | In Frame Del (DEL) | VAF 7/40 reads (18%) | called by mutect2, pindel
- RELCH | c.2551_2556del p.S851_T852del | In Frame Del (DEL) | VAF 6/31 reads (19%) | called by mutect2, pindel, varscan2
- SNRNP40 | c.17del p.K6Sfs*76 | Frame Shift Del (DEL) | VAF 28/68 reads (41%) | called by mutect2, varscan2
- SRSF2 | c.587_594del p.S196* | Frame Shift Del (DEL) | VAF 26/89 reads (29%) | called by mutect2, pindel, varscan2
- STAT5B | c.665T>C p.L222P | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TENM1 | c.7027_7028del p.G2343Rfs*5 | Frame Shift Del (DEL) | VAF 19/58 reads (33%) | called by mutect2, pindel*, varscan2*
- UQCRFS1 | c.715_719delinsA p.H239Sfs*32 | Frame Shift Del (DEL) | VAF 17/125 reads (14%) | called by pindel, varscan2*
- USP25 | c.1209-9_1210del p.X403_splice | Splice Site (DEL) | VAF 3/35 reads (9%) | called by mutect2, pindel
- ACAN | c.5346A>T p.I1782= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as COSV100718331, COSV61368598; called by muse, mutect2, varscan2
- ADAMTS14 | c.3117G>C p.T1039= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as COSV100941647, COSV64604833; called by muse, mutect2
- AKAP14 | c.144C>A p.I48= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as COSV100538320; called by muse, mutect2, varscan2
- AKAP8 | c.252A>G p.P84= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs1230982032, COSV99511980; called by muse, mutect2, varscan2
- ALPK3 | c.1443G>A p.K481= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV99360407, COSV99361155; called by muse, mutect2, varscan2
- ATP6V0B | c.543C>A p.I181= | Silent (SNP) | VAF 57/91 reads (63%) | catalogued as COSV52543843; called by muse, mutect2, varscan2
- AURKC | c.180T>A p.A60= (on ENST00000302804 / NM_001015878.2; = p.A26= on NM_003160.3) | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV100248887; called by muse, mutect2, varscan2
- AVPR1A | c.987C>T p.T329= | Silent (SNP) | VAF 36/51 reads (71%) | catalogued as rs1369669235, COSV100146865; called by muse, mutect2, varscan2
- C6orf118 | c.102A>T p.G34= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV100024617; called by muse, mutect2, varscan2
- CA8 | c.600C>T p.C200= | Silent (SNP) | VAF 32/63 reads (51%) | catalogued as COSV58774101; called by muse, mutect2, varscan2
- CASR | c.2748G>A p.T916= (on ENST00000490131; = p.T993= on NM_000388.4) | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs917914806, COSV56139506, COSV99949071; called by mutect2, varscan2
- CCDC27 | c.600G>A p.L200= | Silent (SNP) | VAF 51/113 reads (45%) | catalogued as COSV99622624; called by muse, mutect2, varscan2
- CDX4 | c.90C>A p.G30= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as rs1403078383, COSV100999107, COSV100999139; called by muse, mutect2, varscan2
- CLVS1 | c.504C>G p.V168= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as COSV100370131; called by muse, mutect2, varscan2
- COL16A1 | c.2145G>A p.G715= | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as COSV99594707; called by muse, mutect2, varscan2
- COL8A2 | c.756T>C p.G252= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV100291238; called by muse, mutect2, varscan2
- CPEB4 | c.210T>A p.I70= | Silent (SNP) | VAF 32/149 reads (21%) | catalogued as COSV99437231; called by muse, mutect2, varscan2
- CPSF3 | c.393C>T p.S131= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV99432899; called by muse, mutect2, varscan2
- CYP26A1 | c.1143T>C p.F381= | Silent (SNP) | VAF 23/38 reads (61%) | catalogued as COSV99814792; called by muse, mutect2, varscan2
- DCSTAMP | c.996A>G p.P332= | Silent (SNP) | VAF 169/236 reads (72%) | catalogued as COSV99886626; called by muse, mutect2, varscan2
- DDC | c.1218G>A p.L406= | Silent (SNP) | VAF 40/103 reads (39%) | catalogued as rs746737558, COSV100779488; called by muse, mutect2, varscan2
- DHX9 | c.2289G>T p.G763= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV100841431; called by muse, varscan2
- DOCK11 | c.2955C>A p.P985= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV52249393, COSV99354062; called by muse, mutect2, varscan2
- EIF2B5 | c.1233G>A p.A411= (on ENST00000647909; = p.A403= on NM_003907.3) | Silent (SNP) | VAF 31/66 reads (47%) | catalogued as rs143448763; ClinVar: likely benign; called by muse, mutect2, varscan2
- GPC5 | c.126G>T p.L42= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV100994390; called by muse, mutect2, varscan2
- GPRC5A | c.1032G>T p.P344= | Silent (SNP) | VAF 30/128 reads (23%) | catalogued as COSV99185585; called by muse, mutect2, varscan2
- GPRIN2 | c.24G>T p.P8= | Silent (SNP) | VAF 12/129 reads (9%) | catalogued as rs140651048, COSV100966410; called by muse, mutect2, varscan2
- IKBKE | c.1536T>C p.N512= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV100898274; called by muse, mutect2, varscan2
- IPO8 | c.144G>T p.V48= | Silent (SNP) | VAF 39/90 reads (43%) | catalogued as COSV99804989, COSV99805441; called by muse, mutect2, varscan2
- KERA | c.285C>A p.T95= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as COSV99899483; called by muse, mutect2, varscan2
- LAMA5 | c.10134C>A p.L3378= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV99440485, COSV99442709; called by muse, mutect2, varscan2
- LRFN2 | c.1941G>A p.P647= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs771853430, COSV57824464; called by muse, varscan2
- LST1 | c.285T>C p.Y95= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs781158507, COSV99279080; called by muse, mutect2, varscan2
- MERTK | c.2031G>C p.G677= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as COSV99774782; called by muse, mutect2, varscan2
- MYH14 | c.1053G>T p.S351= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs377216969, COSV99223058; called by muse, mutect2, varscan2
- MYH2 | c.5137C>T p.L1713= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as COSV99820357; called by muse, mutect2, varscan2
- MYOM2 | c.36A>G p.R12= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs369564350, COSV50713893; called by muse, mutect2, varscan2
- NFATC1 | c.813C>T p.N271= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs367845640; called by muse, mutect2, varscan2
- NLRP7 | c.2109C>A p.T703= (on ENST00000340844 / NM_206828.3; = p.T675= on NM_139176.3) | Silent (SNP) | VAF 145/282 reads (51%) | catalogued as COSV100052858, COSV60171341; called by muse, mutect2, varscan2
- NPY5R | c.1173T>A p.T391= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as COSV100642809; called by muse, mutect2, varscan2
- OPRPN | c.627C>T p.A209= | Silent (SNP) | VAF 30/78 reads (38%) | catalogued as COSV101271091; called by muse, mutect2, varscan2
- OR5K3 | c.123G>T p.G41= | Silent (SNP) | VAF 37/155 reads (24%) | catalogued as COSV101051654; called by muse, mutect2, varscan2
- PLXNA1 | c.2670C>T p.G890= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV99303301; called by muse, mutect2, varscan2
- POTED | c.474C>T p.I158= | Silent (SNP) | VAF 30/47 reads (64%) | catalogued as COSV55049254; called by muse, mutect2, varscan2
- POTEF | c.828G>T p.L276= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as COSV100664996; called by muse, mutect2, varscan2
- PRDM9 | c.2571G>A p.E857= | Silent (SNP) | VAF 27/134 reads (20%) | catalogued as COSV99690581, COSV99691453; called by muse, mutect2, varscan2
- PRSS12 | c.804G>T p.T268= | Silent (SNP) | VAF 27/52 reads (52%) | catalogued as rs535801422, COSV99628368; called by muse, mutect2, varscan2
- RAD51AP2 | c.2520A>G p.T840= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as COSV101208355; called by muse, mutect2, varscan2
- SEC11C | c.255G>T p.R85= | Silent (SNP) | VAF 39/176 reads (22%) | catalogued as COSV100231031, COSV55311216; called by muse, mutect2, varscan2
- SGMS2 | c.291C>T p.I97= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV100763478; called by muse, mutect2, varscan2
- SULT1A1 | c.573C>G p.L191= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as COSV100131899; called by muse, mutect2, varscan2
- TLR1 | c.9C>T p.S3= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV100458561; called by muse, mutect2, varscan2
- TMEM150B | c.231C>G p.L77= | Silent (SNP) | VAF 23/136 reads (17%) | catalogued as COSV100442375; called by muse, mutect2, varscan2
- TMPRSS6 | c.1455A>T p.T485= | Silent (SNP) | VAF 18/100 reads (18%) | catalogued as COSV100695874, COSV60977548; called by muse, mutect2, varscan2
- TRAV8-6 | c.168G>T p.V56= | Silent (SNP) | VAF 74/104 reads (71%) | called by muse, mutect2, varscan2
- UBE4B | c.1416A>G p.L472= (on ENST00000343090 / NM_001105562.3; = p.L343= on NM_006048.5) | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as rs778728074, COSV99476891; called by muse, mutect2, varscan2
- UGP2 | c.1413A>C p.S471= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV99708233; called by muse, mutect2, varscan2
- USH2A | c.5373G>C p.L1791= | Silent (SNP) | VAF 47/318 reads (15%) | catalogued as rs876657628, COSV100236736; ClinVar: likely benign; called by muse, mutect2, varscan2
- USH2A | c.3429A>G p.T1143= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as rs531289860, COSV100236739; called by muse, mutect2, varscan2
- VPS16 | c.1527G>A p.Q509= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as COSV100988506; called by muse, mutect2, varscan2
- XIRP2 | c.1989C>A p.V663= (on ENST00000628543; = p.V838= on NM_152381.6) | Silent (SNP) | VAF 38/66 reads (58%) | catalogued as COSV99743906; called by muse, mutect2, varscan2
- ZCCHC9 | c.237A>C p.L79= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs1320348274, COSV99562667; called by mutect2, varscan2
- ZNF543 | c.615G>T p.G205= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV100386806; called by muse, mutect2, varscan2
- ZNF550 | c.426G>A p.P142= | Silent (SNP) | VAF 166/362 reads (46%) | catalogued as rs371770030; called by muse, mutect2, varscan2
- ZNF676 | c.360G>C p.V120= (on ENST00000650058; = p.V88= on NM_001001411.3) | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as COSV101236234; called by mutect2, varscan2
- ACSL6 | c.993+103C>T | Intron (SNP) | VAF 4/18 reads (22%) | catalogued as rs1463964738, COSV99733930; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73849261 T>A | 5'Flank (SNP) | VAF 9/12 reads (75%) | called by muse, mutect2, varscan2
- GABRA3 | c.-26-29864G>T | Intron (SNP) | VAF 17/67 reads (25%) | catalogued as COSV100942890; called by muse, mutect2, varscan2
- IFNA4 | c.-2C>T | 5'UTR (SNP) | VAF 33/80 reads (41%) | catalogued as COSV101427068; called by muse, mutect2, varscan2
- MAGEA5 | n.198G>T | RNA (SNP) | VAF 24/93 reads (26%) | called by muse, mutect2, varscan2
- MIR509-3 | n.53C>T | RNA (SNP) | VAF 46/148 reads (31%) | catalogued as rs781816035; called by muse, mutect2, varscan2
- OCLNP1 | n.129C>T | RNA (SNP) | VAF 32/170 reads (19%) | called by muse, varscan2
- PDE4DIP | c.637-7087A>G | Intron (SNP) | VAF 25/79 reads (32%) | catalogued as COSV100519778, COSV57703633; called by muse, mutect2, varscan2
- PLXNA4 | c.1371+4339C>A | Intron (SNP) | VAF 14/43 reads (33%) | catalogued as COSV100324840; called by muse, mutect2, varscan2
- RPL13A | c.256+73C>G | Intron (SNP) | VAF 6/70 reads (9%) | catalogued as rs771769638, COSV99201319; called by muse, mutect2
- SSX2 | c.*1C>G | 3'UTR (SNP) | VAF 26/92 reads (28%) | called by mutect2, varscan2
- TMEM132E | chr17:34578945 T>A | 5'Flank (SNP) | VAF 51/153 reads (33%) | catalogued as rs778222069; called by muse, mutect2, varscan2
- UBTFL2 | n.67G>T | RNA (SNP) | VAF 65/197 reads (33%) | called by muse, mutect2, varscan2
- VN1R10P | n.847T>G | RNA (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
